CCDI case PBBPDS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/c54853f7-a3d7-44a2-8ab9-b7088a75be5c

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 0.3 years (105 days).

Biospecimens (3 samples)
- Sample 0DETFG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DETFM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DETFO: Tissue type: Tumor; Specimen type: Solid Tissue.
